Somatic mutation profile of tumor specimen C3L-00993-01 (aliquot CPT0102790009) from CPTAC case C3L-00993, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.6 years (27,610 days).
Specimen C3L-00993-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d0b2f9e-e16b-487f-b0b8-56f5e236dd80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00993-31 (Blood Derived Normal), aliquot CPT0101090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fadd943-30e8-4ab4-8594-053fa2590190

The open-access MAF lists 346 somatic variants for this specimen: 235 protein-altering or splice-affecting, 72 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 72, Intron 14, Nonsense Mutation 10, 5'UTR 8, RNA 7, Frame Shift Del 7, 3'UTR 5, Splice Site 5, In Frame Del 3, Splice Region 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 174/405 reads (43%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 104/552 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749195557, CM1314783; called by muse, mutect2, varscan2
- ABCF3 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 86/964 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV53052576; called by muse, mutect2
- ACTL7B | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs1337191302; called by muse, mutect2, varscan2
- ADAM19 | c.1375G>A p.G459S | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252193734; called by muse, mutect2, varscan2
- ALMS1 | c.10304A>G p.K3435R | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs187607395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASB15 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV99306854; called by muse, mutect2, varscan2
- ASL | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562503544, COSV100508943; called by muse, mutect2, varscan2
- ASPN | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.173); catalogued as rs200074927; called by muse, mutect2
- ATAT1 | c.976C>T p.P326S (on ENST00000376485; = p.P314S on NM_001031722.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.355); catalogued as rs1219934247; called by muse, mutect2, varscan2
- ATIC | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as rs754023595; called by muse, mutect2, varscan2
- ATP2C1 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 64/400 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs764282152, COSV100146591; called by muse, mutect2, varscan2
- ATXN2 | c.1262C>T p.S421L (on ENST00000550104; = p.S261L on NM_002973.4) | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV66483209; called by muse, mutect2, varscan2
- B3GNT3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752385665, COSV59438987; called by muse, mutect2, varscan2
- CDH18 | c.1754C>T p.T585I | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV99933755; called by muse, mutect2, varscan2
- CDH8 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs372550272; called by muse, mutect2, varscan2
- CEP250 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs773533323; called by muse, varscan2
- CFHR2 | c.517T>C p.S173P | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV66380841; called by muse, mutect2, varscan2
- CHAT | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | PolyPhen benign (0.098); catalogued as rs377156965; called by muse, mutect2, varscan2
- CNBD1 | c.1277C>A p.A426E | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV73072468, COSV73073318; called by muse, varscan2
- COL4A4 | c.4817G>A p.G1606E | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767901025, CM099459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO2A | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs143420950, COSV59665070; called by muse, mutect2
- CSMD3 | c.6029C>T p.S2010L (on ENST00000297405 / NM_001363185.1; = p.S1906L on NM_052900.3) | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867017303; called by muse, mutect2, varscan2
- CSRNP1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs766961372, COSV56190215; called by muse, varscan2
- DCTN4 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 81/161 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766970015, COSV69782577; called by muse, mutect2, varscan2
- DDX60L | c.1775C>G p.S592C | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1033048625, COSV52715366; called by muse, mutect2, varscan2
- DIP2B | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 44/312 reads (14%) | catalogued as rs1171011310, COSV56585584; called by muse, mutect2, varscan2
- DISP1 | c.4214C>G p.T1405R | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV52655877; called by muse, mutect2, varscan2
- DVL1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.83); catalogued as rs1254209708, COSV66678109; called by muse, mutect2, varscan2
- ELAC1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs745589685, COSV53996391; called by muse, mutect2, varscan2
- ELAPOR2 | c.1593+1del p.X531_splice (on ENST00000450689 / NM_001142749.3; = p.X364_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 30/166 reads (18%) | catalogued as COSV51890883; called by mutect2, pindel, varscan2
- ELOA2 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 27/587 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs963166141, COSV55295168; called by muse, mutect2
- EPHA5 | c.205G>T p.V69F | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV99900809; called by muse, mutect2
- EPHB1 | c.2896C>A p.L966M | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV101212770; called by muse, mutect2, varscan2
- FAP | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as rs1228796587; called by muse, mutect2, varscan2
- FFAR1 | c.240del p.V81Sfs*20 | Frame Shift Del (DEL) | VAF 55/243 reads (23%) | catalogued as rs780726156; called by mutect2, pindel, varscan2
- GATA2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs768133841; called by muse, mutect2, varscan2
- GATA2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs778562222, COSV62006398; called by muse, mutect2, varscan2
- GCG | c.234G>C p.L78F | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64962288; called by muse, mutect2, varscan2
- GPD2 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs553714328, COSV100133823; called by muse, mutect2, varscan2
- GPR101 | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV53238509; called by muse, mutect2, varscan2
- GYPA | c.137-2A>G p.X46_splice | Splice Site (SNP) | VAF 37/274 reads (14%) | catalogued as COSV51635304; called by muse, mutect2, varscan2
- HMCN1 | c.9638G>C p.R3213P | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54901168; called by muse, mutect2, varscan2
- IGHV4-61 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 75/571 reads (13%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.046); catalogued as rs1555560849; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1557G>T p.M519I | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV56303716; called by muse, mutect2, varscan2
- IQGAP2 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1344430879, COSV57178316; called by muse, mutect2, varscan2
- IRF9 | c.554G>C p.S185T | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs777271237; called by muse, mutect2, varscan2
- ITGAX | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs745926416, COSV51643009; called by muse, mutect2, varscan2
- JRK | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101401060; called by muse, mutect2, varscan2
- KAT2A | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1347629766, COSV52424926; called by muse, mutect2, varscan2
- KCNA5 | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.195); catalogued as COSV52905980; called by muse, mutect2, varscan2
- KCNMA1 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759339608; called by muse, mutect2, varscan2
- KCNT2 | c.1033C>G p.R345G | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV54093604; called by muse, mutect2, varscan2
- KLF7 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs146378446, COSV58742840; called by muse, mutect2, varscan2
- KLHL21 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775339390; called by muse, mutect2, varscan2
- LETM2 | c.938G>A p.R313H (on ENST00000379957 / NM_001286819.2; = p.R218H on NM_144652.3) | Missense Mutation (SNP) | VAF 56/1068 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1371184301; called by muse, mutect2
- LPO | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs769385010, COSV51857378; called by muse, mutect2, varscan2
- LRRC4B | c.1388G>C p.G463A | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated, low confidence (0.92); PolyPhen possibly damaging (0.794); catalogued as rs749356572; called by muse, mutect2, varscan2
- LSM14A | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs1483411745, COSV70885103; called by muse, mutect2, varscan2
- MEGF10 | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57259413; called by muse, mutect2, varscan2
- MIER1 | c.499G>T p.E167* (on ENST00000355356 / NM_001077701.3; = p.E184* on NM_020948.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV62531822; called by mutect2, varscan2
- MTMR7 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs201283564; called by muse, mutect2, varscan2
- MTURN | c.165C>T p.H55= | Splice Region (SNP) | VAF 33/126 reads (26%) | catalogued as rs557008817; called by muse, mutect2, varscan2
- MUC12 | c.1630C>A p.P544T (on ENST00000379442; = p.P401T on NM_001164462.1) | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as rs1342594408; called by muse, mutect2, varscan2
- MYLK | c.2797G>A p.V933M | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1064967; called by muse, mutect2, varscan2
- MYOM2 | c.4201G>A p.V1401I | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs781627298, COSV50711850; called by muse, mutect2, varscan2
- NKX2-8 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177558428, COSV51873037; called by muse, mutect2
- NRXN3 | c.1270C>T p.R424W (on ENST00000335750 / NM_001330195.2; = p.R51W on NM_004796.6) | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748055286, COSV59755799, COSV59799087; called by muse, mutect2, varscan2
- OR2L2 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63550740; called by muse, mutect2, varscan2
- OR4K15 | c.809T>C p.V270A (on ENST00000305051; = p.V246A on NM_001005486.1) | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs771537501, COSV100520995; called by muse, mutect2, varscan2
- OR5D18 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61736233; called by muse, mutect2, varscan2
- OR7G3 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59640972; called by muse, mutect2, varscan2
- PABPC4L | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69929106, COSV69930367; called by muse, mutect2, varscan2
- PCDH10 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV52088148, COSV52090615; called by muse, mutect2, varscan2
- PCDH9 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs376583062, COSV60546646; called by muse, mutect2, varscan2
- PDIA3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs759578661, COSV100295139; called by muse, mutect2, varscan2
- PLCH1 | c.2084G>T p.R695L (on ENST00000340059 / NM_001130960.2; = p.R707L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs755690420; called by muse, mutect2, varscan2
- PPP1R26 | c.1203C>A p.D401E | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1280972886; called by muse, mutect2, varscan2
- PRMT1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as rs746207559; called by muse, mutect2, varscan2
- PRR14L | c.4292A>G p.Q1431R | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs778160268; called by muse, mutect2, varscan2
- RAB9B | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99685976; called by muse, mutect2, varscan2
- RFX7 | c.70G>C p.E24Q (on ENST00000559447 / NM_001368074.1; = p.E121Q on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57959191; called by muse, mutect2, varscan2
- RHBDF1 | c.1765del p.H589Tfs*30 | Frame Shift Del (DEL) | VAF 43/248 reads (17%) | catalogued as COSV99244618; called by mutect2, pindel, varscan2
- RIPOR2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773866451, COSV52420249; called by muse, mutect2, varscan2
- RIPOR3 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 42/381 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs761255631; called by muse, mutect2, varscan2
- ROS1 | c.1621G>T p.G541W | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63863575; called by muse, mutect2, varscan2
- RRAS2 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV56330154; called by muse, mutect2, varscan2
- SGCZ | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101168548; called by muse, mutect2, varscan2
- SGCZ | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65999322; called by muse, mutect2, varscan2
- SLCO2B1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs543049597, COSV56935587; called by muse, mutect2
- SLF2 | c.2074G>C p.D692H | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53277324; called by muse, mutect2, varscan2
- SMCO1 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759849329; called by muse, mutect2, varscan2
- SNAI1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.097); catalogued as rs1263892553; called by muse, mutect2, varscan2
- SORCS3 | c.3472C>G p.Q1158E | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs1163263863, COSV63818549; called by muse, mutect2
- SPATA20 | c.1277G>T p.G426V (on ENST00000356488 / NM_001258372.1; = p.G442V on NM_022827.4) | Missense Mutation (SNP) | VAF 214/415 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs769732740; called by muse, mutect2, varscan2
- SPRTN | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV50478193; called by muse, mutect2, varscan2
- SYN3 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs375260226; called by muse, mutect2, varscan2
- TENM3 | c.3719G>A p.R1240H | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs753536722, COSV69308534; called by muse, mutect2, varscan2
- TGIF2LX | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 137/233 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV52214847, COSV52214920; called by muse, mutect2, varscan2
- TRABD2B | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs1028304175, COSV101437780; called by muse, mutect2, varscan2
- TTN | c.97790G>A p.R32597H (on ENST00000591111; = p.R25173H on NM_003319.4) | Missense Mutation (SNP) | VAF 111/523 reads (21%) | PolyPhen possibly damaging (0.556); catalogued as rs767961553, COSV60028248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP14 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.043); catalogued as rs1384037426; called by muse, mutect2, varscan2
- XIRP2 | c.7899C>A p.S2633R (on ENST00000628543; = p.S2808R on NM_152381.6) | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772842255, COSV54738086; called by muse, mutect2, varscan2
- XKR3 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58885355, COSV58887036; called by muse, mutect2
- ZBTB5 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 47/238 reads (20%) | catalogued as rs548741554; called by muse, mutect2, varscan2
- ZFHX4 | c.8366C>G p.A2789G | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs1312486070; called by muse, mutect2, varscan2
- ZNF512B | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 54/530 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1358357275; called by muse, mutect2, varscan2
- ZNF587 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs199951884; called by muse, varscan2
- ZNF831 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.594); catalogued as COSV100926383; called by muse, mutect2, varscan2
- ADAM9 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 69/874 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADAMTS1 | c.673_699del p.E225_D233del | In Frame Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel
- ADAMTS12 | c.3308A>T p.E1103V | Missense Mutation (SNP) | VAF 235/422 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS12 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 232/422 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHCTF1 | c.4286C>T p.A1429V (on ENST00000366508; = p.A1403V on NM_015446.5) | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.9796T>C p.Y3266H | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AQP4 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATAD2B | c.3665A>T p.N1222I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ATG4C | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); called by muse, varscan2
- C10orf71 | c.353del p.P118Hfs*16 | Frame Shift Del (DEL) | VAF 23/130 reads (18%) | called by mutect2, pindel, varscan2
- CATSPER3 | c.305T>A p.V102D | Missense Mutation (SNP) | VAF 208/581 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CCDC168 | c.13936A>C p.M4646L | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCT6B | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CD207 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CEP126 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- CLDN15 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 171/374 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CPN2 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 83/418 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- CSMD3 | c.9714G>T p.Q3238H (on ENST00000297405 / NM_001363185.1; = p.Q3069H on NM_052900.3) | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); called by muse, mutect2
- CUL9 | c.2317G>A p.G773S | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYFIP2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | called by muse, varscan2
- DAAM2 | c.2634G>T p.E878D | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DENND5A | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- DGKG | c.549G>T p.M183I | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- DNAH5 | c.13261A>C p.T4421P | Missense Mutation (SNP) | VAF 182/910 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DOCK1 | c.3820G>C p.E1274Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DRAXIN | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DSE | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- EBLN1 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EIF4G3 | c.1535C>A p.P512Q | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ENAM | c.2247T>G p.N749K | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ENOX2 | c.676C>A p.R226S (on ENST00000338144 / NM_001382520.1; = p.R197S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/225 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ERVV-2 | c.1124A>C p.D375A | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2
- FBN2 | c.1121G>C p.R374P | Missense Mutation (SNP) | VAF 29/475 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- FBXO3 | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- FCRL1 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FGF13 | c.681A>C p.R227S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GEMIN5 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 132/228 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GFRA1 | c.255C>A p.Y85* | Nonsense Mutation (SNP) | VAF 76/240 reads (32%) | called by muse, mutect2, varscan2
- GLRA1 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 256/495 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNA13 | c.374T>G p.F125C | Missense Mutation (SNP) | VAF 55/414 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GPR87 | c.755A>G p.Q252R | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- GRIN2B | c.2143G>C p.D715H | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); called by muse, varscan2
- GRM5 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.11); called by muse, mutect2
- H2BC1 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- HAL | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 70/528 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- HHLA2 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2
- IDO2 | c.110del p.P37Qfs*17 (on ENST00000389060; = p.P50Qfs*17 on NM_194294.2) | Frame Shift Del (DEL) | VAF 39/429 reads (9%) | called by mutect2, pindel
- IGKV1D-8 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- IGKV3-7 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.195); called by mutect2, varscan2
- IGLV3-27 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 73/353 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- IL26 | c.429G>T p.R143S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ITSN2 | c.3164C>G p.P1055R | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KCNT2 | c.3060A>T p.R1020S | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KDM4B | c.1231del p.E411Rfs*108 | Frame Shift Del (DEL) | VAF 43/122 reads (35%) | called by pindel, varscan2
- KIF2C | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 90/413 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIRREL1 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LATS1 | c.2453G>T p.S818I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LENG8 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- LIMCH1 | c.1178A>G p.E393G | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- LRP1B | c.11668C>G p.L3890V | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- LRRC4C | c.1782C>A p.H594Q | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- LRRTM1 | c.1136C>A p.T379N | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- LSG1 | c.1738_1767del p.G580_E589del | In Frame Del (DEL) | VAF 26/322 reads (8%) | called by mutect2, pindel
- MAN2A2 | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MARCHF11 | c.358G>C p.G120R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- MMP17 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MYO18B | c.2130C>G p.H710Q | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- MYO9B | c.2598C>G p.D866E | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MYOCD | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- NCKAP1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NECAP1 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- NMRK1 | c.318-1G>T p.X106_splice | Splice Site (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- OBSCN | c.13431C>G p.D4477E | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- OBSL1 | c.3772T>G p.F1258V | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OR5J2 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR9Q2 | c.838del p.V280Wfs*2 | Frame Shift Del (DEL) | VAF 40/177 reads (23%) | called by mutect2, pindel, varscan2
- OTOGL | c.4477G>C p.E1493Q (on ENST00000547103; = p.E1484Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- P4HA2 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPPA2 | c.2144T>C p.I715T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2
- PCDH18 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDGFRA | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PGM1 | c.1350T>A p.F450L | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU3F3 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PPP1R2B | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 60/392 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRKDC | c.6301G>T p.V2101F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PRR12 | c.1028G>T p.R343L (on ENST00000615927; = p.R1164L on NM_020719.3) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRM | c.3874G>T p.A1292S | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RABGAP1L | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RGS11 | c.100C>A p.Q34K (on ENST00000397770 / NM_183337.3; = p.Q13K on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- RP1L1 | c.4336G>A p.G1446S | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SF3B1 | c.2121G>T p.L707F | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGF29 | c.579dup p.D194* | Frame Shift Ins (INS) | VAF 47/326 reads (14%) | called by mutect2, pindel, varscan2
- SKIL | c.1291_1300del p.S431Yfs*33 | Frame Shift Del (DEL) | VAF 22/230 reads (10%) | called by mutect2, pindel
- SLC17A8 | c.1495G>T p.G499W | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SLC25A29 | c.254G>T p.R85L (on ENST00000359232 / NM_001039355.3; = p.R19L on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPIRE2 | c.993_998del p.L332_R333del | In Frame Del (DEL) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- SRPX | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SUGP1 | c.1530A>G p.E510= | Splice Region (SNP) | VAF 55/222 reads (25%) | called by muse, mutect2, varscan2
- SYNE1 | c.16896+1G>T p.X5632_splice (on ENST00000367255 / NM_182961.4; = p.X5561_splice on NM_033071.3) | Splice Site (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- TAF4B | c.2556T>A p.Y852* | Nonsense Mutation (SNP) | VAF 37/214 reads (17%) | called by muse, mutect2, varscan2
- TCEAL8 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TCP11L1 | c.239A>T p.H80L | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCTN2 | c.1099+1G>C p.X367_splice | Splice Site (SNP) | VAF 45/345 reads (13%) | called by muse, mutect2, varscan2
- TECPR2 | c.2165G>T p.G722V | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TENT5C | c.878A>C p.Q293P | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- THAP11 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THNSL1 | c.1263T>G p.I421M | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TMEM200A | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM94 | c.4051G>C p.G1351R | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53I11 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TREM1 | c.252G>C p.R84S | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TRIM22 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- TRIM42 | c.1712T>G p.L571R | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.68); called by mutect2, varscan2
- TRPC5 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- TSHR | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 38/463 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, mutect2
- UNC79 | c.745A>T p.K249* (on ENST00000393151 / NM_001346218.2; = p.K72* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- UPF2 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- USH2A | c.8055C>G p.D2685E | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP14 | c.1225+7A>G | Splice Region (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- ZNF236 | c.3829G>T p.D1277Y | Missense Mutation (SNP) | VAF 142/386 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ZNF407 | c.513A>T p.K171N | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF431 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ZNF436 | c.1237A>T p.T413S | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF662 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF729 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ADAM23 | c.681C>T p.F227= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs558319181, COSV52214289, COSV52230290, COSV52231072; called by muse, mutect2, varscan2
- ADRA1A | c.600C>T p.I200= | Silent (SNP) | VAF 42/269 reads (16%) | catalogued as rs369356439; called by muse, mutect2, varscan2
- ALDH2 | c.183T>G p.T61= | Silent (SNP) | VAF 50/191 reads (26%) | called by muse, mutect2, varscan2
- ANKFN1 | c.543C>A p.A181= | Silent (SNP) | VAF 191/336 reads (57%) | called by muse, mutect2, varscan2
- ASCC3 | c.1467C>T p.Y489= | Silent (SNP) | VAF 80/406 reads (20%) | catalogued as rs201166961; called by muse, mutect2, varscan2
- ATP2A2 | c.1944G>A p.T648= | Silent (SNP) | VAF 18/488 reads (4%) | catalogued as rs1448615410; called by muse, mutect2
- ATP9B | c.3216C>T p.A1072= | Silent (SNP) | VAF 67/316 reads (21%) | catalogued as rs754909371; called by muse, mutect2, varscan2
- BANK1 | c.963T>C p.Y321= | Silent (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
- BHLHE23 | c.528G>T p.A176= (on ENST00000370346; = p.A192= on NM_080606.4) | Silent (SNP) | VAF 63/241 reads (26%) | catalogued as rs768091062, COSV100947617; called by muse, mutect2, varscan2
- C1orf127 | c.1530C>A p.P510= | Silent (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- CASQ1 | c.39G>T p.P13= | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2
- CAV3 | c.258G>C p.L86= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV57480706; called by muse, mutect2, varscan2
- CCT8L2 | c.288C>T p.T96= | Silent (SNP) | VAF 92/344 reads (27%) | catalogued as COSV100743101; called by muse, mutect2, varscan2
- CDH10 | c.204A>C p.T68= | Silent (SNP) | VAF 22/288 reads (8%) | called by muse, mutect2
- CEP131 | c.579G>A p.S193= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as rs758196590, COSV53951162; called by muse, mutect2, varscan2
- CNST | c.1956C>T p.D652= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs747984736; called by muse, mutect2, varscan2
- CREBBP | c.2679G>A p.S893= | Silent (SNP) | VAF 56/294 reads (19%) | catalogued as rs587783474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX18 | c.1923T>C p.F641= | Silent (SNP) | VAF 44/200 reads (22%) | called by muse, varscan2
- DHX33 | c.1191G>T p.T397= | Silent (SNP) | VAF 39/207 reads (19%) | called by muse, mutect2, varscan2
- DOCK6 | c.2058C>T p.S686= | Silent (SNP) | VAF 44/221 reads (20%) | catalogued as rs549496660; called by muse, mutect2, varscan2
- EFCAB8 | c.2607G>A p.T869= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as rs765075908; called by muse, mutect2, varscan2
- FAM20C | c.1467C>T p.D489= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs1183155948; called by muse, mutect2, varscan2
- FEV | c.111C>T p.S37= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs1204435004; called by muse, mutect2, varscan2
- GAL3ST4 | c.1113C>A p.V371= | Silent (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- GAREM2 | c.2199C>T p.R733= | Silent (SNP) | VAF 8/23 reads (35%) | called by muse, varscan2
- GPR75 | c.402G>A p.K134= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as rs764049715; called by muse, mutect2, varscan2
- HDAC1 | c.1149G>A p.A383= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs751023967; called by muse, mutect2, varscan2
- IL7 | c.525A>G p.K175= | Silent (SNP) | VAF 37/278 reads (13%) | called by muse, mutect2, varscan2
- INSRR | c.516G>T p.L172= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- ITGA11 | c.621C>T p.G207= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs778041873; called by muse, mutect2, varscan2
- ITGA8 | c.2535T>A p.P845= | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- KCNJ15 | c.240T>C p.L80= | Silent (SNP) | VAF 61/309 reads (20%) | called by muse, mutect2, varscan2
- KIF17 | c.918G>C p.T306= | Silent (SNP) | VAF 43/298 reads (14%) | catalogued as rs755200199; called by muse, mutect2, varscan2
- LRP1B | c.5046C>G p.G1682= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as COSV104431910; called by muse, mutect2
- LRRC3B | c.123T>C p.S41= | Silent (SNP) | VAF 36/238 reads (15%) | catalogued as rs113252125; called by muse, mutect2, varscan2
- LRRTM1 | c.1137C>A p.T379= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as COSV54439585; called by muse, mutect2, varscan2
- MTMR3 | c.981A>T p.R327= | Silent (SNP) | VAF 67/228 reads (29%) | called by muse, mutect2, varscan2
- MYH1 | c.5034G>T p.V1678= | Silent (SNP) | VAF 31/216 reads (14%) | catalogued as COSV56847032; called by muse, mutect2, varscan2
- NASP | c.1602A>C p.T534= | Silent (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- NEB | c.17151G>A p.V5717= | Silent (SNP) | VAF 49/355 reads (14%) | called by muse, mutect2, varscan2
- NF1 | c.2694G>T p.L898= | Silent (SNP) | VAF 102/525 reads (19%) | catalogued as rs1060503923; called by muse, mutect2, varscan2
- NUP37 | c.57G>T p.V19= | Silent (SNP) | VAF 39/177 reads (22%) | called by muse, mutect2, varscan2
- OLFM1 | c.117G>A p.A39= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2
- OR2B6 | c.129G>C p.L43= | Silent (SNP) | VAF 93/284 reads (33%) | called by muse, mutect2, varscan2
- OR5K1 | c.441G>C p.G147= | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as rs187850780; called by muse, mutect2
- OR8J1 | c.303G>T p.L101= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as COSV57319791; called by muse, mutect2
- PALM | c.1065C>T p.A355= | Silent (SNP) | VAF 57/321 reads (18%) | called by muse, mutect2, varscan2
- PARK7 | c.309C>T p.A103= | Silent (SNP) | VAF 83/492 reads (17%) | catalogued as rs368221790; called by muse, mutect2, varscan2
- PLA1A | c.597C>A p.A199= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- PLA2G6 | c.2085A>G p.T695= | Silent (SNP) | VAF 61/329 reads (19%) | called by muse, mutect2, varscan2
- PLEC | c.2784C>T p.V928= (on ENST00000322810 / NM_201380.4; = p.V818= on NM_000445.5) | Silent (SNP) | VAF 45/332 reads (14%) | catalogued as rs782527676; called by muse, mutect2, varscan2
- PLG | c.1953A>G p.E651= | Silent (SNP) | VAF 111/293 reads (38%) | called by muse, mutect2, varscan2
- POGZ | c.210C>T p.T70= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as rs746514487; called by muse, mutect2, varscan2
- PPP4R3C | c.138A>G p.S46= | Silent (SNP) | VAF 57/135 reads (42%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.216C>A p.L72= (on ENST00000295902; = p.L16= on NM_198859.4) | Silent (SNP) | VAF 64/286 reads (22%) | catalogued as rs1278550599; called by muse, mutect2, varscan2
- RALGPS2 | c.1572G>A p.V524= | Silent (SNP) | VAF 22/186 reads (12%) | called by muse, varscan2
- RNF152 | c.534C>T p.V178= | Silent (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- RNF40 | c.510T>C p.G170= | Silent (SNP) | VAF 35/222 reads (16%) | called by muse, mutect2, varscan2
- SLC16A12 | c.1512G>A p.E504= | Silent (SNP) | VAF 47/182 reads (26%) | catalogued as COSV57950669; called by muse, mutect2, varscan2
- SLC35E4 | c.325C>A p.R109= | Silent (SNP) | VAF 57/253 reads (23%) | called by muse, mutect2, varscan2
- SLC44A3 | c.1821G>A p.S607= (on ENST00000271227 / NM_001114106.3; = p.S559= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/249 reads (20%) | catalogued as rs757493214, COSV54729481; called by muse, mutect2, varscan2
- SLC5A2 | c.1689C>T p.L563= | Silent (SNP) | VAF 66/497 reads (13%) | called by muse, mutect2, varscan2
- STYXL2 | c.2097A>G p.S699= | Silent (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- TCP11L2 | c.901C>T p.L301= | Silent (SNP) | VAF 41/251 reads (16%) | called by muse, mutect2, varscan2
- THSD7A | c.1143C>T p.S381= | Silent (SNP) | VAF 53/315 reads (17%) | called by muse, mutect2, varscan2
- THSD7B | c.3789G>A p.Q1263= (on ENST00000272643; = p.Q1261= on NM_001316349.2) | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as rs267598899, COSV55732869, COSV99752150; called by muse, mutect2, varscan2
- TRIM49B | c.255C>T p.F85= | Silent (SNP) | VAF 67/372 reads (18%) | catalogued as rs1159621256; called by muse, mutect2, varscan2
- VAV1 | c.903G>T p.R301= | Silent (SNP) | VAF 74/201 reads (37%) | catalogued as rs1400000816; called by muse, mutect2, varscan2
- WASHC5 | c.687G>A p.L229= | Silent (SNP) | VAF 32/291 reads (11%) | catalogued as COSV59196284; called by muse, mutect2, varscan2
- WDHD1 | c.867G>A p.S289= | Silent (SNP) | VAF 24/237 reads (10%) | catalogued as rs370843677; called by muse, mutect2
- ZEB1 | c.3228G>A p.E1076= | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as rs755327991, COSV58051728; called by muse, varscan2
- ZFHX2 | c.4534C>T p.L1512= | Silent (SNP) | VAF 207/582 reads (36%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3863C>G | RNA (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- AC034198.1 | n.154G>T | RNA (SNP) | VAF 79/407 reads (19%) | called by muse, mutect2, varscan2
- ADCY10 | c.148+49C>T | Intron (SNP) | VAF 10/258 reads (4%) | catalogued as rs1193543502; called by muse, mutect2
- ANK1 | c.5619+47G>T | Intron (SNP) | VAF 48/660 reads (7%) | called by muse, mutect2
- AP000769.1 | n.71C>G | RNA (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- ARSA | c.466-33C>T | Intron (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- CCDC198 | c.656-3915C>T | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- CDK10 | chr16:89682773 G>T | 5'Flank (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812245 A>T | 3'Flank (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- COL4A3 | c.-24C>A | 5'UTR (SNP) | VAF 33/202 reads (16%) | called by muse, mutect2, varscan2
- DNAJC19 | c.-76G>C | 5'UTR (SNP) | VAF 44/455 reads (10%) | called by muse, mutect2
- EFCAB11 | c.-2C>G | 5'UTR (SNP) | VAF 36/181 reads (20%) | called by muse, mutect2, varscan2
- ELMOD1 | c.-86+1005A>G | Intron (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- EPS8L1 | c.-5G>C | 5'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- EYS | c.1767-6941G>C | Intron (SNP) | VAF 9/71 reads (13%) | called by mutect2, varscan2
- HACE1 | c.-5C>G | 5'UTR (SNP) | VAF 47/219 reads (21%) | catalogued as rs1195724532; called by muse, mutect2, varscan2
- IMPDH1 | chr7:128409952 C>G | 5'Flank (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- ISY1-RAB43 | c.-7C>G | 5'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- KCNIP4 | c.62-421198C>G | Intron (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- LHX9 | c.*2661G>T | 3'UTR (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- LRRC7 | c.647+35206C>A | Intron (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- MIR124-2 | chr8:64377493 G>A | 5'Flank (SNP) | VAF 74/320 reads (23%) | called by muse, varscan2
- NPHS1 | c.1440+30G>A | Intron (SNP) | VAF 66/193 reads (34%) | called by muse, mutect2, varscan2
- OR56B3P | n.430G>T | RNA (SNP) | VAF 109/260 reads (42%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157149 C>T | 3'Flank (SNP) | VAF 46/344 reads (13%) | catalogued as rs973149129; called by muse, mutect2, varscan2
- PCOLCE | c.463+301C>T | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as rs1471622162; called by muse, mutect2, varscan2
- PDE8B | c.651-29G>T | Intron (SNP) | VAF 133/330 reads (40%) | catalogued as COSV53731343; called by muse, mutect2, varscan2
- PRSS1 | c.200+405T>A | Intron (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- RABL6 | c.*95C>T | 3'UTR (SNP) | VAF 44/236 reads (19%) | catalogued as rs749309329; called by muse, mutect2, varscan2
- RAD51D | c.*929A>T | 3'UTR (SNP) | VAF 191/468 reads (41%) | catalogued as rs1422061440; called by muse, mutect2, varscan2
- RPL8 | c.500-298G>C | Intron (SNP) | VAF 24/309 reads (8%) | called by muse, mutect2
- SLC6A10P | n.2985C>A | RNA (SNP) | VAF 68/409 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-25 | n.82A>T | RNA (SNP) | VAF 29/175 reads (17%) | called by muse, mutect2, varscan2
- TAFA2 | c.-1-10665T>A | Intron (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- TPTE2 | c.*9G>T | 3'UTR (SNP) | VAF 28/204 reads (14%) | catalogued as COSV99690965; called by muse, mutect2, varscan2
- TUBB7P | n.537G>A | RNA (SNP) | VAF 80/537 reads (15%) | called by muse, varscan2
- UGCG | c.-5G>A | 5'UTR (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- UQCRB | c.*721G>A | 3'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- ZNF461 | c.-33G>A | 5'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
